Somatic mutation profile of tumor specimen TCGA-D7-8572-01A (aliquot TCGA-D7-8572-01A-11D-2340-08) from TCGA case TCGA-D7-8572, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.1 years (20,870 days).
Specimen TCGA-D7-8572-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d63f8585-b6cb-4571-b3e6-fe63887fe8cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8572-10A (Blood Derived Normal), aliquot TCGA-D7-8572-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6edb3181-da3f-4021-a674-3396665a3d20

The open-access MAF lists 198 somatic variants for this specimen: 150 protein-altering or splice-affecting, 46 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 46, Splice Site 5, Nonsense Mutation 5, Frame Shift Del 4, Splice Region 2, In Frame Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1425+1G>A p.X475_splice (on ENST00000521381 / NM_181523.3; = p.X205_splice on NM_181504.4) | Splice Site (SNP) | VAF 16/83 reads (19%) | hotspot (GDC flag); catalogued as rs587777709, CS148401, CS148402, CS164183, COSV57123381, COSV57132744, COSV57140308; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RIMS1 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 29/139 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- AC253536.7 | c.327G>A p.R109= | Splice Region (SNP) | VAF 7/43 reads (16%) | catalogued as rs779750125, COSV53159502; called by muse, mutect2
- ACOT12 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs182807009, COSV56895207; called by muse, mutect2, varscan2
- ADGRB3 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65398061; called by muse, mutect2, varscan2
- ANK3 | c.2775G>T p.L925F (on ENST00000280772 / NM_001320874.2; = p.L59F on NM_001149.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55060625; called by muse, mutect2, varscan2
- ARAP3 | c.902+1G>T p.X301_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | catalogued as COSV53350972; called by muse, varscan2
- ARID4B | c.496A>T p.R166W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51604212; called by muse, mutect2, varscan2
- ARL13B | c.1097A>T p.D366V (on ENST00000394222 / NM_001174150.2; = p.D259V on NM_144996.4) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as COSV57398602; called by muse, mutect2, varscan2
- ASCC3 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV61228840; called by muse, mutect2, varscan2
- ATP8A2 | c.3319C>A p.L1107M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.79); catalogued as COSV99680183; called by muse, mutect2, varscan2
- BCL6 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.286); catalogued as rs755544927, COSV51652501; called by muse, mutect2, varscan2
- BORCS5 | c.210G>C p.L70F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV53801187, COSV53802847; called by muse, mutect2, varscan2
- BRWD1 | c.3607T>A p.Y1203N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60896617; called by muse, mutect2
- C3orf70 | c.287A>C p.Q96P | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV58588081; called by muse, mutect2, varscan2
- CAGE1 | c.1423C>T p.R475W (on ENST00000512086; = p.R339W on NM_205864.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746643033, COSV57075904; called by muse, mutect2, varscan2
- CAVIN1 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV63811969; called by muse, mutect2, varscan2
- CDH1 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55731369, COSV55732870, COSV55741714; called by muse, mutect2
- CELSR3 | c.9161G>T p.G3054V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99372619; called by muse, mutect2
- CEP250 | c.1697T>G p.V566G | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61170561; called by muse, mutect2, varscan2
- CFAP94 | c.1867G>A p.V623I (on ENST00000320267 / NM_001352064.2; = p.V629I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs150985883; called by muse, mutect2, varscan2
- CHD8 | c.5666G>A p.R1889H (on ENST00000646647 / NM_001170629.2; = p.R1610H on NM_020920.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777867742, COSV63036682; called by muse, mutect2, varscan2
- CHRNA4 | c.180C>A p.D60E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV64717356, COSV64717701; called by muse, mutect2, varscan2
- CNTN5 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV54315660; called by muse, mutect2
- CNTNAP2 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.169); catalogued as COSV100666828, COSV62188510; called by muse, mutect2, varscan2
- COQ10A | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs148374703, COSV57524829; called by muse, mutect2, varscan2
- CRBN | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1367633045, COSV51641179; called by muse, mutect2, varscan2
- CREM | c.1021C>T p.P341S (on ENST00000429130; = p.P296S on NM_181571.3) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV100415000; called by muse, mutect2
- CSMD3 | c.8051A>T p.N2684I (on ENST00000297405 / NM_001363185.1; = p.N2580I on NM_052900.3) | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52111492, COSV52195148; called by muse, mutect2, varscan2
- CSMD3 | c.6941G>T p.R2314I (on ENST00000297405 / NM_001363185.1; = p.R2210I on NM_052900.3) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV52195177; called by muse, mutect2, varscan2
- CSRNP2 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57334370; called by muse, mutect2, varscan2
- CUL5 | c.1471A>G p.N491D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV67609017; called by muse, mutect2, varscan2
- CYLC1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV61412592; called by muse, mutect2, varscan2
- CYP51A1 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV50152052; called by muse, mutect2, varscan2
- DCC | c.1732G>T p.V578F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1187262857, COSV59105515; called by muse, mutect2, varscan2
- DDX43 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV64812888; called by muse, mutect2, varscan2
- DNAH17 | c.1440C>G p.D480E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as rs767171083, COSV67755574; called by muse, mutect2, varscan2
- DNAH3 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 31/154 reads (20%) | catalogued as COSV54525253; called by muse, mutect2, varscan2
- DNAH8 | c.6175C>A p.L2059M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59450558; called by muse, mutect2, varscan2
- DSC2 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51865342; called by muse, mutect2, varscan2
- ECEL1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV58812567; called by muse, mutect2, varscan2
- EMSY | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58260861; called by muse, mutect2, varscan2
- ENTPD6 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs140692182; called by muse, mutect2, varscan2
- ESCO2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV59414765; called by muse, mutect2, varscan2
- ESRRG | c.991A>T p.I331L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV63162913; called by muse, mutect2
- ESYT1 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.779); catalogued as COSV57273312; called by muse, mutect2, varscan2
- EVI5 | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64827437; called by muse, mutect2
- F2 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61315936; called by muse, mutect2, varscan2
- FAF2 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV56131231; called by muse, mutect2, varscan2
- FAT3 | c.2571C>A p.D857E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766425087, COSV53118341; called by muse, mutect2, varscan2
- FAT4 | c.7543T>A p.F2515I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100628198, COSV58683458; called by muse, mutect2
- FBN1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs773685409, COSV57318259; called by muse, mutect2, varscan2
- FLG | c.12098A>G p.N4033S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64242576; called by muse, mutect2, varscan2
- GABPB1 | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV55015169; called by muse, mutect2
- GALNT17 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61148854, COSV61159742, COSV61200321; called by muse, mutect2, varscan2
- GLB1L2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60278806; called by muse, mutect2, varscan2
- GLG1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs745573951, COSV52664016, COSV99215873; called by muse, mutect2, varscan2
- GLTP | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV59172941; called by muse, mutect2
- GPC5 | c.1601T>G p.I534S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV65601836; called by muse, mutect2, varscan2
- GRAP2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1164470654, COSV59995487; called by muse, mutect2, varscan2
- HDAC9 | c.474A>C p.K158N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67774338; called by muse, mutect2, varscan2
- HELLS | c.2120G>A p.R707K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53297653; called by muse, mutect2, varscan2
- HERC1 | c.5714G>T p.G1905V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71248056; called by muse, mutect2, varscan2
- HERC5 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52040319, COSV52040466; called by muse, mutect2, varscan2
- HNRNPK | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV61088231, COSV61089679; called by muse, mutect2, varscan2
- HOGA1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776161817, COSV56729938; called by muse, mutect2, varscan2
- IFNA10 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 26/463 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs762249251, COSV53331273; called by muse, mutect2
- IL1RAPL1 | c.52A>G p.S18G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV56265649, COSV99043028; called by muse, mutect2, varscan2
- KAT6A | c.2546A>G p.Q849R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV55906646; called by muse, mutect2, varscan2
- KCNA5 | c.1098C>A p.F366L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52906353; called by muse, mutect2, varscan2
- KCNB2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV73049994; called by muse, mutect2, varscan2
- KCND3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1198744961, COSV56181694; called by muse, mutect2, varscan2
- KIFAP3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs201441472, COSV63031622, COSV63034367; called by muse, mutect2, varscan2
- KLHL4 | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as COSV64143047; called by muse, mutect2, varscan2
- KRT73 | c.639A>T p.E213D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256280911, COSV59839495; called by muse, mutect2, varscan2
- KRTAP24-1 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV61089573; called by muse, mutect2, varscan2
- KRTAP27-1 | c.396A>C p.Q132H | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101239811, COSV67001260; called by muse, mutect2, varscan2
- LDLR | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as rs141673997, CD984596, CM128849; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LRP4 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66136075; called by mutect2, varscan2
- LRRFIP2 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60868008; called by muse, mutect2, varscan2
- MARF1 | c.1907C>G p.A636G | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.652); catalogued as COSV60022059, COSV60024137; called by muse, mutect2, varscan2
- MCCC1 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.035); catalogued as COSV55608995; called by muse, mutect2, varscan2
- MFSD9 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763344870, COSV51494030; called by muse, mutect2, varscan2
- MKRN1 | c.224G>C p.C75S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55436937; called by muse, mutect2, varscan2
- MMRN1 | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53338061; called by muse, mutect2, varscan2
- MSL1 | c.1214A>G p.K405R (on ENST00000398532 / NM_001365919.1; = p.K142R on NM_001012241.2) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.986); catalogued as COSV104413272; called by muse, mutect2
- MUC20 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 15/197 reads (8%) | catalogued as rs1347682282; called by muse, mutect2
- MZF1 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV53041706; called by muse, mutect2
- NASP | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs774362498, COSV63113242; called by muse, mutect2, varscan2
- NME7 | c.891C>T p.D297= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV63167269; called by muse, mutect2
- NUBPL | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs35433432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OCA2 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62347194; called by muse, mutect2, varscan2
- OR7D2 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV60139619; called by muse, mutect2, varscan2
- OSBPL1A | c.2237G>A p.C746Y (on ENST00000319481 / NM_080597.4; = p.C233Y on NM_018030.4) | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV60198800; called by muse, mutect2
- PCDHA1 | c.1841C>A p.A614E | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV65374669; called by muse, mutect2, varscan2
- PDE3A | c.991C>G p.R331G | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100761695; called by muse, varscan2
- PDGFRA | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57268608; called by muse, mutect2, varscan2
- PGM3 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780464371, COSV52284210, COSV52285136; called by muse, mutect2, varscan2
- PKD2L2 | c.1724A>T p.K575M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV50366910, COSV50376441; called by muse, mutect2, varscan2
- PRAG1 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757290219, COSV58161762; called by muse, mutect2, varscan2
- PRDM9 | c.429T>A p.S143R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV57003874, COSV57007101; called by muse, mutect2, varscan2
- PRKAA1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs761385811, COSV57183493; called by muse, mutect2, varscan2
- PUM2 | c.829A>C p.T277P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV57581179; called by muse, mutect2, varscan2
- RAD17 | c.1474G>A p.E492K (on ENST00000380774 / NM_133339.2; = p.E481K on NM_002873.1) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.174); catalogued as COSV51457935; called by muse, mutect2, varscan2
- SCN3A | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV51811259, COSV51813491; called by muse, mutect2, varscan2
- SEC63 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV64600043; called by muse, mutect2, varscan2
- SEMA3E | c.1898T>C p.V633A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV57092455; called by muse, mutect2, varscan2
- SEMG2 | c.1218A>G p.I406M | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs778825224, COSV65647530; called by muse, varscan2
- SERINC1 | c.1304T>A p.V435E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV60102175; called by muse, mutect2, varscan2
- SFMBT1 | c.124-1G>T p.X42_splice | Splice Site (SNP) | VAF 7/150 reads (5%) | catalogued as COSV99965834; called by muse, mutect2
- SLC17A5 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.331); catalogued as COSV63287530; called by muse, mutect2, varscan2
- SLC7A4 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV60384227; called by muse, mutect2, varscan2
- SLITRK6 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV68390385; called by muse, mutect2, varscan2
- SMC4 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.159); catalogued as COSV59087388; called by muse, mutect2, varscan2
- SMC4 | c.3613T>G p.F1205V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59087391; called by muse, mutect2, varscan2
- SPAG17 | c.5053+2T>G p.X1685_splice | Splice Site (SNP) | VAF 20/85 reads (24%) | catalogued as rs140829839; called by muse, mutect2, varscan2
- SPTB | c.3958G>A p.A1320T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67632272; called by muse, mutect2, varscan2
- SRP54 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs749487051, COSV53740081; called by muse, mutect2, varscan2
- STAT3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV52888177; called by muse, mutect2
- STAU2 | c.725G>T p.R242L (on ENST00000524300 / NM_001164380.2; = p.R210L on NM_014393.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV63307650, COSV63308483; called by muse, mutect2, varscan2
- STK39 | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV63597595; called by muse, mutect2, varscan2
- STXBP2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.313); catalogued as rs750099959, COSV55403619; called by muse, mutect2, varscan2
- SUSD5 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs552801817, COSV58877765; called by muse, mutect2, varscan2
- TCHP | c.1124T>A p.L375Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57165610; called by muse, mutect2, varscan2
- TET1 | c.5578G>C p.A1860P | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65385140; called by muse, mutect2, varscan2
- TIAM1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV54553422; called by muse, mutect2, varscan2
- TJP1 | c.2135C>A p.A712E | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62042421; called by muse, mutect2, varscan2
- TMEM125 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1374210035, COSV71326932; called by muse, mutect2, varscan2
- TMEM165 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63529196; called by muse, mutect2
- TRIM24 | c.2653C>T p.P885S (on ENST00000343526 / NM_015905.3; = p.P851S on NM_003852.4) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV58972913; called by muse, mutect2, varscan2
- TUBE1 | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV57889449; called by muse, mutect2, varscan2
- UBE3B | c.3188C>T p.T1063M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281060028, COSV61075016; called by muse, mutect2, varscan2
- WDR35 | c.1093A>T p.N365Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV55603169; called by muse, mutect2, varscan2
- WNK3 | c.4563C>A p.S1521R | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63614350; called by muse, mutect2, varscan2
- ZBTB8A | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV57142726; called by muse, mutect2, varscan2
- ZNF415 | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV54701771; called by muse, mutect2, varscan2
- ZNF431 | c.376T>A p.F126I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV60673287; called by muse, mutect2, varscan2
- ZNF813 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV67176668; called by muse, mutect2, varscan2
- ZXDA | c.2227A>C p.S743R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV62388095; called by muse, mutect2, varscan2
- ZXDA | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100699362, COSV100699489; called by muse, mutect2, varscan2
- AGPS | c.1320del p.F440Lfs*8 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- CCDC158 | c.2850_2854del p.S952Hfs*4 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- DST | c.17393T>A p.M5798K (on ENST00000361203 / NM_001374722.1; = p.M3495K on NM_015548.5) | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- HNRNPL | c.1356-1_1363del p.X452_splice | Splice Site (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- MLLT6 | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PNISR | c.133_138del p.R45_E46del | In Frame Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- ROBO2 | c.1949_1958del p.T650Rfs*18 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- SEC16A | c.2659_2691del p.G887_S897del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel
- SPATA31A3 | c.871T>A p.C291S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.047); called by mutect2, varscan2
- TPCN2 | c.348_360del p.W118Afs*3 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- ADAM9 | c.480C>T p.H160= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV65946711; called by muse, mutect2, varscan2
- ALOXE3 | c.1422C>T p.I474= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV59075993; called by muse, mutect2, varscan2
- ARHGEF12 | c.4389C>A p.S1463= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV63105052; called by muse, mutect2, varscan2
- BMP6 | c.1437G>A p.A479= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as rs774047873, COSV51666018; called by muse, mutect2, varscan2
- BUD13 | c.1770C>G p.S590= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV52768490; called by muse, mutect2, varscan2
- CCNF | c.195G>C p.L65= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53540289; called by muse, mutect2, varscan2
- CELSR3 | c.7380G>A p.E2460= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV50868197; called by muse, mutect2, varscan2
- CKAP2L | c.345G>A p.K115= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as COSV56696669; called by muse, mutect2, varscan2
- COX10 | c.1326C>T p.P442= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs776202901, COSV55405407; called by muse, mutect2
- CPNE8 | c.1575A>G p.K525= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV58843339, COSV58844098; called by muse, mutect2, varscan2
- FUT6 | c.840C>T p.Y280= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs760949055, COSV99744277; called by muse, mutect2, varscan2
- GNLY | c.312C>T p.R104= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1433493473, COSV99808820; called by muse, mutect2
- GPRC5A | c.753C>T p.A251= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV50007832; called by muse, mutect2, varscan2
- GRIA4 | c.2601G>C p.V867= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV56899171; called by muse, mutect2, varscan2
- H2AC11 | c.54C>G p.R18= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs147278636; called by muse, mutect2, varscan2
- HLCS | c.1911C>A p.I637= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as COSV60794109; called by muse, mutect2, varscan2
- IFNA6 | c.534A>G p.S178= | Silent (SNP) | VAF 73/354 reads (21%) | catalogued as COSV66506445; called by muse, mutect2, varscan2
- IGHMBP2 | c.666G>C p.T222= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV54822790; called by muse, mutect2, varscan2
- IGKV1-5 | c.177G>A p.Q59= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs578213821; called by muse, mutect2, varscan2
- JAGN1 | c.399C>T p.G133= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV57062076; called by muse, mutect2, varscan2
- JAK2 | c.1446G>A p.Q482= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1488724976, COSV67614548; called by muse, mutect2, varscan2
- LMO7 | c.1482C>T p.D494= (on ENST00000357063; = p.D224= on NM_015842.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV58538076; called by muse, mutect2, varscan2
- MAGI2 | c.2439C>T p.A813= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs779558075, COSV62664415; called by muse, mutect2, varscan2
- NALCN | c.4473G>A p.K1491= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1245462603, COSV51938915; called by muse, mutect2, varscan2
- NAV3 | c.3141T>C p.D1047= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV57083089; called by muse, mutect2, varscan2
- NISCH | c.2217C>T p.F739= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs369874506; called by muse, mutect2, varscan2
- OR10J1 | c.828C>G p.T276= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV71128918; called by muse, mutect2, varscan2
- OR6A2 | c.138C>A p.I46= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs1161183331, COSV60265096; called by muse, mutect2, varscan2
- OR8B3 | c.585C>T p.N195= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs1332722048, COSV63541762; called by muse, mutect2, varscan2
- PCDH9 | c.2220A>G p.K740= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV60554861; called by muse, mutect2, varscan2
- PDCD1 | c.237G>A p.L79= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1266801463, COSV57691419; called by muse, mutect2, varscan2
- PDHA2 | c.1098C>A p.I366= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV54779506; called by muse, mutect2, varscan2
- PNMA8B | c.81G>A p.P27= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV66536759, COSV66537343; called by muse, mutect2
- POLI | c.372G>T p.L124= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99470849; called by muse, mutect2, varscan2
- RPLP0 | c.774C>G p.T258= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV56108586; called by muse, mutect2, varscan2
- SCAF1 | c.3054A>C p.R1018= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62183507; called by muse, mutect2, varscan2
- SEMG2 | c.1413A>G p.S471= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV65647535; called by muse, mutect2
- SYT6 | c.1470C>T p.I490= (on ENST00000610222 / NM_001366225.1; = p.I405= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs370803872; called by muse, mutect2, varscan2
- THNSL1 | c.1908G>A p.G636= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100896111; called by muse, mutect2
- TNKS1BP1 | c.1284C>T p.F428= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs768441436, COSV64101217; called by muse, mutect2, varscan2
- UBA2 | c.684A>C p.A228= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV55828585; called by muse, mutect2, varscan2
- VAV3 | c.2112A>G p.G704= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV58383390; called by muse, mutect2, varscan2
- WDR64 | c.1623G>A p.G541= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs753046788, COSV63796427; called by muse, mutect2, varscan2
- ZNF397 | c.261G>A p.E87= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV54350980; called by muse, mutect2, varscan2
- ZNF79 | c.681G>A p.G227= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV61071054; called by muse, mutect2, varscan2
- ZZEF1 | c.7719C>T p.S2573= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs745485852, COSV67557867; called by muse, mutect2, varscan2
- CCDC6 | c.*234G>A | 3'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as rs781286341, COSV99569167; called by mutect2, varscan2
- EPHA6 | c.1895-8899T>A | Intron (SNP) | VAF 13/60 reads (22%) | catalogued as COSV101060620, COSV101060893, COSV67560356; called by muse, mutect2, varscan2
